Gene-level copy-number profile of tumor specimen TCGA-EJ-7115-01A from TCGA case TCGA-EJ-7115, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.7 years (23,986 days).
Specimen TCGA-EJ-7115-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.c338847c-e006-46bf-ba8d-d7ffac0b5961.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-7115-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bfa3de5c-5495-4c15-b76e-39ef839bd792

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 5,453; copy number 2: 54,304; copy number 3: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-7115-01A-11D-2112-01): tumor purity 0.59, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:55,838,801–58,859,394, 54 genes (within-gene range 0–1): HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1, AC008940.1, MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1, AC025470.2, SALL4P1, ACTBL2, LINCR-0003, AC008780.1, AC106822.1, LINC02225, LINC02101, AC008786.1, PGAM1P1, PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1.
- chr6:68,040,290–68,329,899, 4 genes: AL646090.2, AL646090.1, AL593844.1, LINC02549.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,074. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
